Surgical pathology report (de-identified scan), TCGA case TCGA-3C-AALI, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Columbia University, specimen TCGA-3C-AALI-01A (Primary Tumor).

[page 1 of 3]
Name: [REDACTED]
MRN: [REDACTED]
D.O.B. (Age:)
Sex: F
Location:

Path No.: [REDACTED]
Date Obtained:
Date Received:
Physician:

SURGICAL PATHOLOGY

****See Addendum/Procedure****

ICD-O-3

SPECIMEN:

- A: Lymph node, right axilla sentinel node, biopsy
- B: Breast, right, lumpectomy
- C: Lymph nodes, right axilla, dissection

*Carcinoma, infiltrating duct
NOS 8500/3
Site ^{CHE} (B) Breast NOS C50.9
with (B) Breast, upper-outer
quadrant C50.4
7/5/11/14*

DIAGNOSIS(ES):

- A. Lymph node, right axilla sentinel node, biopsy:
- Carcinoma in 1 sentinel node following carcinoma of right breast.
- B. Breast, right, lumpectomy:
- Carcinoma, invasive ductal type, moderately-differentiated, with focal micropapillary features, Nottingham's score 5 (2+2+1).
- Carcinoma, intraductal, comedo type with microcalcifications.
- Lobular neoplasia, focal, classical type.
- Fibrocystic disease, proliferative, with apocrine metaplasia, sclerosing adenosis and microcalcifications.
- Cicatricial fibrosis and organizing granulation tissue with fat necrosis, consistent with previous biopsy site.
- Fibroadenoma, microscopic.
- C. Lymph nodes, right axilla, dissection:
- No evidence of carcinoma in 14 lymph nodes.

Date Dictated:

CLINICAL INFORMATION: Breast cancer.

GROSS DESCRIPTION:

The specimen is received in three parts.

Part A is received fresh from the operating room for frozen section diagnosis in a container labeled with the patient's name and "R sentinel lymph node". It consists of one firm tan to red lymph node measuring 2.0 x 1.8 x 1.0 cm. The specimen is serially sectioned. Submitted in toto in three cassettes labeled AFS, A1 and A2. AFS = frozen section, A1 - A2 = remaining tissue.

Part B is received unfixed in a container labeled with the patient's name and "R breast lumpectomy". It consists of a piece of yellow-white fibrofatty tissue measuring 10.5 x 9.0 x 6.0 cm. An ellipse of skin is not present. An X-ray is received. A localization needle is not noted. A short suture is noted indicating the superior margin and a row of long sutures are noted indicating the lateral margin. A mass is palpated in the center. The superficial surface is inked yellow

[page 2 of 3]
and the deep surface is inked black. The specimen is serially sectioned. On cut section, the mass is tan, firm, poorly circumscribed and measures 3.2 x 3.0 x 3.0 cm. The mass comes to 0.3 cm of the superficial, 0.5 cm of the deep and 2.5 cm of the lateral margins. The tissue is composed of 60% fat and 40% intermixed firm tan-white parenchyma. Representative sections are submitted in 29 cassettes labeled B1 - B29.

Legend: B1 = mass and closest deep surface,
B2 = mass and closest superficial surface(B1 and B2 = full thickness of mass),
B3 - B8 = mass with adjacent deep margin
B9 - B17 = superficial margin over mass
B18 - B19 = mass
B20 - B21 = superior
B22 - B23 = deep margin in lateral part(closest to mass)
B24 - B25 = lateral
B26 - B27 = inferior
B28 - B29 = medial.

Part C is received unfixed in a container labeled with the patient's name and "R axillary lymph node dissection". It consists of two pieces of yellow-red fatty tissue measuring 4.0 x 2.7 x 1.0 cm and 10.0 x 7.0 x 1.0 cm. A suture is noted attached to one end of the larger piece of fatty tissue. Fourteen lymph nodes measuring from 0.6 x 0.5 x 0.5 cm to 3.5 x 1.5 x 1.0 cm are identified. The lymph nodes are submitted in toto 10 cassettes labeled C1 - C10.

Legend: C1 = five intact nodes, C2 - C5 = one bisected node in each cassettes, C6 = one intact node, C7 - C8 = one large quadrisected node, C9 - C10 = nodes closest to suture(larger node is bisected).

INTRAOPERATIVE CONSULTATION:

AFS: Metastatic carcinoma in lymph node.

Performed by: Resident:

Interpreted by: Attending:

MICROSCOPIC DESCRIPTION:

- I. TYPE OF SPECIMEN: Right breast, excisional biopsy/lumpectomy
Right axillary node dissection
- II. LOCATION OF THE TUMOR: Upper outer quadrant
- III. TYPE OF NEOPLASM:
Carcinoma, invasive - ductal type NOS with micropapillary features
Histological Grading: Moderately differentiated
(Nuclear grade 2 and Tubular & Glandular differentiation grade 2)
Ductal carcinoma in situ, nuclear grade 3, multifocal 10%
Intraductal comedo subtype
Necrosis is present within the intraductal subtype
Lobular neoplasia, type A (monomorphic), Focal in 2 of 29 slides
- IV. GROSS/MICRO FINAL INVASIVE TUMOR SIZE INTERPRETATION: 3.2 x 3.0 x 3.0 cm.
- V. BORDERS OF INVASIVE NEOPLASM: Ill-defined
- VI. VASCULAR SPACE INVASION: Present in lymphatics
- VII. CALCIFICATION: Present in both malignant and benign areas
- VIII. NIPPLE: N/A
- IX. SKIN: N/A

[page 3 of 3]
- X. ADJACENT BREAST TISSUE: Fibroadenoma (size 0.2 cm.)
Cystic disease, proliferative
- XI. SURGICAL MARGIN: No carcinoma is identified on surgical margins
Tumor distance from closest deep (slide "B1") margin: 0.6 cm
- XII. AXILLARY LYMPH NODES:
TOTAL: 15
HIGH POINT: 2
SENTINEL NODE: 1
- XIII. POSITIVE LYMPH NODES:
TOTAL: 1
HIGH POINT: 0
SENTINEL NODE: 1
- DEGREE OF INVOLVEMENT: Extensive replacement
- EXTRANODAL EXTENSION: Present
- XIV. PECTORAL MUSCLE: No pectoral muscle identified

This report has been reviewed electronically and signed on by

Interpreted by: Attending:

The diagnosis was rendered by the attending pathologist.

Addendum

Date Ordered:

Status: Signed Out

ADDENDUM

Slides were reviewed by
agreement with the original diagnosis.

The diagnosis rendered is in

This procedure/addenda has been electronically reviewed and signed on by

Interpreted by: Attending:

Note: Immunohistochemistry testing performed at was developed and its performance characteristics determined by the

These tests were interpreted in conjunction with external positive and internal negative controls, unless otherwise noted. It has not been cleared or approved by the US FDA. This test is used for clinical purposes only. It should not be regarded as investigational or for research.

Source: NCI Genomic Data Commons file 220667b7-e6fa-4f50-aec1-8f93535f3115 (TCGA-3C-AALI.84E6A935-1A49-4BC1-9669-3DEA161CF6FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).